Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4476, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4476-01A (Primary Tumor).

■

Diagnosis:

Total gastrectomy preparation with gastric carcinoma extending to within 5 cm of the oral resection margin at most, located on the side of the lesser curvature, with a maximum diameter of 3.5 cm, characterized histologically as a poorly differentiated adenocarcinoma (gastric carcinoma of diffuse type). Invasive tumor spread within all parietal layers of the stomach extending to the level of the subserosa, the perigastric tissue and circumscribed within peripancreatic fatty tissue of a small adjacent part of the pancreas.

Oral and aboral resection margin and also omentum tumor-free. Twelve of thirty-three lymph nodes with metastases of the gastric carcinoma. Other lymph nodes with uncharacteristically reactive lesions.

Tumor stage thus pT4 pN3a (12/33) L1 V0; ■

Source: NCI Genomic Data Commons file e9093937-616d-4995-97ab-9170b5140545 (TCGA-CG-4476.0299E1B2-0691-4C74-B0C0-9FE0B4CA1AA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).